TARGET case TARGET-40-PANGPE — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97b855c6-cf08-50ec-801b-7e884cd24dd1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 13 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 13.1 years (4,794 days); Year of diagnosis: 2004; Metastasis at diagnosis: No Metastasis; Days to last follow up: 3,378 days (9.2 years).
   Treatment given: Protocol identifier: P9851.

Follow-up (2 entries)
- Days to follow up: 833 days (2.3 years); Days to first event: 833 days (2.3 years); First event: Second Malignant Neoplasm.
- Days to follow up: 3,378 days (9.2 years); Year of follow up: 2014.

Biospecimens (2 samples)
- Sample TARGET-40-PANGPE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PANGPE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3378
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PANGPE-01A-01:
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 94
- % Normal: Top from Biopsy: 1
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 5
- PASS/FAIL: pass
